Somatic mutation profile of tumor specimen CDDP-ABKI-TTP1-A (aliquot CDDP-ABKI-TTP1-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABKI, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60 years.
Specimen CDDP-ABKI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a0f4f38-3864-4516-8dd8-b8192fa863af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABKI-NB1-A (Blood Derived Normal), aliquot CDDP-ABKI-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c07ab3d-ec74-4c1c-93aa-0e07adb9fb61

The open-access MAF lists 1,472 somatic variants for this specimen: 979 protein-altering or splice-affecting, 307 silent, 186 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 833, Silent 307, Intron 75, Nonsense Mutation 71, RNA 35, 3'UTR 29, Frame Shift Del 27, Splice Site 24, 5'UTR 21, 5'Flank 19, Splice Region 11, Frame Shift Ins 8.

Variants (750 of 1,472; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTRT3 | chr3:169764945 G>A | 3'Flank (SNP) | VAF 38/302 reads (13%) | catalogued as rs199422272, CR034844; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.3053G>A p.G1018D | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs1569498896, CM145030; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HBB | c.190C>T p.H64Y | Missense Mutation (SNP) | VAF 130/409 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs33922873, CM940919, CM973274; ClinVar: pathogenic / other; called by muse, mutect2, varscan2
- LDLR | c.1381G>A p.G461S | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs193922568, CM060313; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1530G>T p.Q510H | Missense Mutation (SNP) | VAF 147/394 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM117756, COSV61005626, COSV61006865; called by muse, mutect2, varscan2
- SF3B1 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 17/94 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs776846119, COSV59205460, COSV59217320; called by muse, mutect2, varscan2
- TP53 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 395/516 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.4004A>C p.K1335T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV55291286; called by muse, mutect2, varscan2
- ABCA10 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as rs1403074494; called by muse, mutect2, varscan2
- ABCA13 | c.3607C>A p.H1203N | Missense Mutation (SNP) | VAF 74/356 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV101330055; called by muse, mutect2, varscan2
- ABCB1 | c.1809T>A p.D603E | Missense Mutation (SNP) | VAF 134/198 reads (68%) | SIFT tolerated (0.25); PolyPhen benign (0.14); catalogued as rs757574649, COSV55956327; called by muse, mutect2, varscan2
- ACTN3 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566281518; called by muse, mutect2
- ADAM15 | c.437C>A p.T146N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.217); catalogued as COSV55061823; called by muse, mutect2, varscan2
- ADAMTS12 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV100711556; called by muse, mutect2, varscan2
- ADGB | c.245T>G p.F82C | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58855659; called by muse, mutect2, varscan2
- ADGRB1 | c.2810C>T p.A937V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1401265875; called by muse, mutect2, varscan2
- ADRA1A | c.1161G>T p.R387S | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV52359857; called by muse, mutect2, varscan2
- ALX4 | c.1162C>A p.R388S | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV61327560; called by muse, mutect2, varscan2
- AMPH | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV100343959, COSV57751863; called by muse, mutect2
- ANGPT4 | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as rs908074894; called by muse, mutect2, varscan2
- ANK2 | c.5351G>T p.R1784L | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV100000542; called by muse, mutect2, varscan2
- ANKMY1 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 170/279 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773307154; called by muse, varscan2
- ANKRD30B | c.4006C>T p.P1336S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.031); catalogued as rs1246630076; called by muse, mutect2, varscan2
- AQR | c.1930A>T p.N644Y | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV50029516; called by muse, mutect2, varscan2
- ARID4A | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.339); catalogued as rs773709444; called by muse, mutect2, varscan2
- ARSK | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs149960886; called by muse, varscan2
- BARHL1 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.327); catalogued as rs1260821206; called by muse, mutect2, varscan2
- BCHE | c.200G>C p.G67A | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs769202966; called by muse, mutect2, varscan2
- BCL6B | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.351); catalogued as COSV53427892; called by muse, mutect2, varscan2
- BRSK1 | c.525C>A p.F175L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV58668022; called by muse, mutect2, varscan2
- BSX | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs778269524, COSV58005338; called by muse, mutect2, varscan2
- BTBD8 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61545016; called by muse, mutect2, varscan2
- BTK | c.43C>A p.Q15K | Missense Mutation (SNP) | VAF 112/157 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as CD015203, CM950158; called by muse, mutect2, varscan2
- C6 | c.1751C>G p.S584W | Missense Mutation (SNP) | VAF 31/354 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as COSV54704717; called by muse, mutect2
- C7 | c.983-1G>C p.X328_splice | Splice Site (SNP) | VAF 67/352 reads (19%) | catalogued as COSV100495965; called by muse, varscan2
- CACNA2D1 | c.296G>C p.R99P | Missense Mutation (SNP) | VAF 31/313 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV62380645; called by muse, mutect2, varscan2
- CACNA2D3 | c.1870C>A p.H624N | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV55589780; called by muse, mutect2, varscan2
- CADPS | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 90/183 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99032524; called by muse, mutect2, varscan2
- CAMK1G | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748689663; called by muse, mutect2, varscan2
- CAMSAP1 | c.3860G>T p.R1287L | Missense Mutation (SNP) | VAF 98/197 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV104395396; called by muse, mutect2, varscan2
- CAP2 | c.386T>C p.M129T | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.396); catalogued as rs756287106; called by muse, mutect2, varscan2
- CAPN14 | c.580T>C p.S194P | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.137); catalogued as rs1159908731; called by muse, varscan2
- CASKIN1 | c.2779G>A p.D927N | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs768552379; called by muse, mutect2
- CATSPERB | c.2347G>A p.D783N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV56435261; called by muse, varscan2
- CCDC168 | c.8021C>T p.S2674L | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.053); catalogued as COSV70554756; called by muse, mutect2, varscan2
- CCDC180 | c.4643G>T p.R1548M | Missense Mutation (SNP) | VAF 95/153 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs150778871; called by muse, mutect2, varscan2
- CCNT1 | c.1054A>G p.S352G | Missense Mutation (SNP) | VAF 90/307 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs745356084; called by muse, mutect2, varscan2
- CD1E | c.193C>T p.H65Y | Missense Mutation (SNP) | VAF 216/334 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs1313305017, COSV63771741; called by muse, mutect2, varscan2
- CDH10 | c.2132G>T p.R711L | Missense Mutation (SNP) | VAF 59/494 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as COSV52593768; called by muse, mutect2, varscan2
- CDH10 | c.1382C>A p.A461D | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52571533; called by muse, mutect2, varscan2
- CDH10 | c.1121C>A p.S374Y | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.141); catalogued as COSV52581026; called by muse, mutect2, varscan2
- CDH12 | c.2263G>T p.D755Y | Missense Mutation (SNP) | VAF 93/463 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV66400983; called by muse, mutect2, varscan2
- CDH8 | c.938A>G p.Y313C | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54881267; called by muse, mutect2, varscan2
- CDHR2 | c.3735C>G p.S1245R | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV56145869; called by muse, mutect2, varscan2
- CDK5R2 | c.92C>A p.A31E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.354); catalogued as COSV56937035; called by mutect2, varscan2
- CDKL2 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 26/118 reads (22%) | catalogued as rs1355490030, COSV100277031; called by muse, mutect2, varscan2
- CENPF | c.8075T>C p.V2692A | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs775287543; called by muse, mutect2, varscan2
- CFAP70 | c.3149C>T p.T1050I | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.187); catalogued as rs1261854036; called by muse, mutect2, varscan2
- CFAP91 | c.1774G>T p.E592* | Nonsense Mutation (SNP) | VAF 45/141 reads (32%) | catalogued as COSV56345520; called by muse, mutect2, varscan2
- CHST5 | c.1171G>T p.D391Y | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV60340162; called by muse, mutect2, varscan2
- CNTNAP4 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as rs758195382, COSV56665292; called by muse, mutect2, varscan2
- CNTNAP5 | c.3214G>T p.G1072* | Nonsense Mutation (SNP) | VAF 84/186 reads (45%) | catalogued as COSV70475477; called by muse, varscan2
- COL25A1 | c.1926G>T p.G642= | Splice Region (SNP) | VAF 27/121 reads (22%) | catalogued as rs771902612; called by muse, mutect2, varscan2
- COL3A1 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM1412439; called by muse, mutect2, varscan2
- COL6A6 | c.3998T>C p.L1333P | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs763699033; called by muse, mutect2, varscan2
- COL7A1 | c.4935G>T p.P1645= | Splice Region (SNP) | VAF 107/247 reads (43%) | catalogued as COSV100097141; called by muse, mutect2, varscan2
- COP1 | c.1468G>T p.D490Y | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100444040; called by muse, mutect2, varscan2
- CORIN | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56696597; called by muse, mutect2, varscan2
- CREB3L1 | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs766415281; called by muse, mutect2, varscan2
- CRISP2 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs765925773; called by muse, mutect2, varscan2
- CSMD2 | c.9725C>T p.P3242L | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.932); catalogued as rs1214567193; called by muse, mutect2
- CSMD3 | c.4313A>G p.N1438S (on ENST00000297405 / NM_001363185.1; = p.N1334S on NM_052900.3) | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs769028600; called by muse, mutect2, varscan2
- CTNNA2 | c.1636C>G p.R546G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100561623; called by muse, mutect2, varscan2
- CTNND2 | c.2732C>A p.A911E | Missense Mutation (SNP) | VAF 74/331 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58937577; called by muse, mutect2, varscan2
- CUBN | c.7182C>A p.F2394L | Missense Mutation (SNP) | VAF 60/327 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100912676; called by muse, mutect2, varscan2
- CYLC2 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770915404; called by muse, mutect2, varscan2
- CYP2C19 | c.1146del p.K383Rfs*6 | Frame Shift Del (DEL) | VAF 18/111 reads (16%) | catalogued as COSV64909660; called by mutect2, pindel, varscan2
- DBX2 | c.472C>A p.R158S | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV100224417, COSV60337074; called by muse, mutect2, varscan2
- DCX | c.152A>T p.K51I | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99050110; called by muse, mutect2, varscan2
- DDI1 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56379437; called by muse, mutect2, varscan2
- DEFA4 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52405174; called by muse, mutect2, varscan2
- DEFB133 | c.43G>T p.V15F | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.413); catalogued as rs78790513; called by muse, mutect2, varscan2
- DLG2 | c.2391A>C p.K797N | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54682703; called by muse, mutect2
- DMBT1 | c.5510G>A p.R1837H (on ENST00000338354 / NM_001377530.1; = p.R1080H on NM_004406.3) | Missense Mutation (SNP) | VAF 67/493 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs748198152, COSV57537993; called by muse, mutect2, varscan2
- DNAH14 | c.10113C>A p.F3371L (on ENST00000445597; = p.F4379L on NM_001367479.1) | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV59894887, COSV59897026; called by muse, mutect2, varscan2
- DNAH5 | c.9161C>T p.S3054L | Missense Mutation (SNP) | VAF 55/386 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV54244447; called by muse, mutect2, varscan2
- DNAI3 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.614); catalogued as COSV99641648; called by muse, mutect2, varscan2
- DOT1L | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs748856790; called by muse, mutect2, varscan2
- DPP10 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 133/286 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59669342; called by muse, mutect2, varscan2
- DSC2 | c.1604G>C p.R535T | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99199472; called by muse, mutect2, varscan2
- DTX3 | c.1032C>G p.I344M | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54084460; called by muse, mutect2, varscan2
- DUOX2 | c.3955A>T p.T1319S | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV66531219; called by muse, mutect2, varscan2
- DUSP15 | c.325C>T p.R109W (on ENST00000278979 / NM_001320479.1; = p.R112W on NM_080611.4) | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs745824933, COSV54065047; called by muse, mutect2
- ENAM | c.2361G>T p.W787C | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748480572, COSV68536135; called by muse, mutect2, varscan2
- ERICH3 | c.2564G>T p.G855V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs776725780, COSV58598695; called by muse, mutect2, varscan2
- EYA4 | c.209-1G>T p.X70_splice | Splice Site (SNP) | VAF 80/134 reads (60%) | catalogued as rs1441151762; called by muse, mutect2, varscan2
- FAM135B | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV52728853, COSV99425888; called by muse, mutect2, varscan2
- FAM214B | c.645G>T p.E215D | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV100521253; called by muse, mutect2, varscan2
- FAM27E5 | n.277G>A | Splice Region (SNP) | VAF 76/130 reads (58%) | catalogued as rs764075766; called by muse, mutect2, varscan2
- FAM71B | c.454C>A p.L152M | Missense Mutation (SNP) | VAF 92/170 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57227388; called by muse, mutect2, varscan2
- FAM78B | c.579G>C p.M193I | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV57975448; called by muse, mutect2
- FAT3 | c.5527A>G p.T1843A | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs748399384, COSV99961070, COSV99973046; called by muse, mutect2
- FAT3 | c.8317C>A p.R2773S | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV53111551, COSV53127574; called by muse, varscan2
- FAT3 | c.8458G>A p.D2820N | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV53085705; called by muse, varscan2
- FBXL7 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61643919; called by muse, mutect2
- FBXL7 | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100308779, COSV61651948; called by muse, mutect2
- FCAR | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 33/175 reads (19%) | catalogued as COSV62029585; called by muse, mutect2, varscan2
- FCRL5 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.141); catalogued as rs757938999, COSV62516784; called by muse, mutect2, varscan2
- FGD1 | c.2167C>T p.R723W | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs370970773, COSV100910795; ClinVar: uncertain significance; called by muse, mutect2
- FLG | c.10450A>C p.S3484R | Missense Mutation (SNP) | VAF 64/617 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64244143; called by muse, mutect2, varscan2
- FREM1 | c.32C>A p.A11D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV66519473; called by muse, varscan2
- FRY | c.4338G>C p.E1446D | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.009); catalogued as rs376406292; called by muse, mutect2, varscan2
- GABRQ | c.1079G>T p.R360L | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as COSV64781745; called by muse, mutect2, varscan2
- GALC | c.1774G>T p.A592S | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.103); catalogued as rs1360345372, CM970568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCSAML | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 64/275 reads (23%) | catalogued as COSV63577829; called by muse, mutect2, varscan2
- GHR | c.1678T>G p.L560V | Missense Mutation (SNP) | VAF 61/683 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.099); catalogued as COSV100051984; called by muse, mutect2
- GMIP | c.1929C>G p.F643L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV52559632; called by mutect2, varscan2
- GNL3L | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs760007760, COSV60576946; called by muse, mutect2, varscan2
- GOLGA6L22 | c.2266G>T p.E756* | Nonsense Mutation (SNP) | VAF 71/429 reads (17%) | catalogued as rs1443357180; called by muse, varscan2
- GPX6 | c.412G>C p.G138R | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV100724903; called by muse, mutect2, varscan2
- GRIN2A | c.3144C>A p.S1048R | Missense Mutation (SNP) | VAF 51/364 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV58037388; called by muse, mutect2, varscan2
- GRK5 | c.798G>C p.M266I | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100962855; called by muse, mutect2, varscan2
- GRM7 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as rs368337809; called by muse, mutect2, varscan2
- GRM8 | c.2594T>A p.M865K | Missense Mutation (SNP) | VAF 37/391 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV58829168; called by muse, mutect2
- H2BC11 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.833); catalogued as rs775202984; called by muse, varscan2
- HEPH | c.380C>T p.P127L (on ENST00000343002; = p.P181L on NM_138737.5) | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57968474; called by muse, varscan2
- HIPK4 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as rs1473930178, COSV52520602, COSV99397042; called by muse, mutect2, varscan2
- HMCN1 | c.8921T>C p.L2974P | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99638730; called by muse, mutect2, varscan2
- HP1BP3 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs775804235; called by muse, mutect2, varscan2
- HSD3B2 | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 63/342 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as rs1342019935; called by muse, mutect2, varscan2
- HTR1B | c.345G>T p.W115C | Missense Mutation (SNP) | VAF 71/121 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1281433563; called by muse, mutect2, varscan2
- IARS1 | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 65/94 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs780810676; called by muse, mutect2, varscan2
- IFNA2 | c.376del p.V126Wfs*3 | Frame Shift Del (DEL) | VAF 81/180 reads (45%) | catalogued as rs770518311; called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.138C>A p.Y46* | Nonsense Mutation (SNP) | VAF 112/670 reads (17%) | catalogued as rs775040766; called by muse, varscan2
- IL37 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV54491625, COSV54492437, COSV54493067; called by muse, mutect2
- INPP4B | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs571714237; called by muse, mutect2, varscan2
- ITGA2B | c.2747G>A p.C916Y | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as rs1393566865; called by muse, mutect2, varscan2
- ITGB7 | c.2186T>C p.L729P | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV99914034; called by muse, mutect2, varscan2
- ITK | c.90C>G p.F30L | Missense Mutation (SNP) | VAF 160/290 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.26); catalogued as rs756484580, COSV101439935, COSV70061797; called by muse, varscan2
- JRKL | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs1239700983, COSV53592163; called by muse, mutect2, varscan2
- KCNH1 | c.2062T>A p.S688T (on ENST00000271751 / NM_172362.3; = p.S661T on NM_002238.4) | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV99660707; called by muse, mutect2, varscan2
- KCNJ16 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 25/200 reads (13%) | catalogued as COSV52250893; called by muse, mutect2, varscan2
- KCNQ3 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs141821338, COSV66469250; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1755 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.063); catalogued as rs1197492616; called by muse, mutect2, varscan2
- KIF21A | c.3113G>T p.R1038L (on ENST00000361418 / NM_001378440.1; = p.R1025L on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV62776018; called by muse, mutect2, varscan2
- KIF2B | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as COSV52135739; called by muse, mutect2, varscan2
- KLRC3 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 93/193 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs138941727, COSV67249991; called by muse, mutect2, varscan2
- KRT82 | c.684C>T p.D228= | Splice Region (SNP) | VAF 27/76 reads (36%) | catalogued as rs200149668, COSV57786728; called by muse, mutect2, varscan2
- KRTAP4-16 | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 101/262 reads (39%) | SIFT tolerated (0.06); catalogued as rs1200916619; called by muse, mutect2, varscan2
- LCE1A | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 213/404 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as COSV58727976; called by muse, varscan2
- LCE3E | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.043); catalogued as rs369786520; called by muse, mutect2
- LGR4 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as rs779682678, COSV64865727; called by muse, mutect2, varscan2
- LONP2 | c.318C>G p.C106W | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV53526274; called by muse, mutect2, varscan2
- LRRC15 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs150995251, COSV61651190; called by muse, mutect2, varscan2
- LRRC30 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.789); catalogued as rs1441205740, COSV67301507; called by muse, varscan2
- LRRC69 | c.650G>C p.G217A | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.053); catalogued as COSV59252539; called by muse, mutect2
- LRRCC1 | c.2230G>T p.E744* | Nonsense Mutation (SNP) | VAF 13/87 reads (15%) | catalogued as COSV100835221, COSV64483225; called by muse, mutect2, varscan2
- LRRTM4 | c.1461C>G p.D487E | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.888); catalogued as COSV69139311; called by muse, mutect2, varscan2
- LYPD3 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54989406; called by muse, mutect2, varscan2
- MACROH2A1 | c.73G>T p.V25L | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56896742; called by muse, mutect2, varscan2
- MAGEA12 | c.744A>T p.Q248H | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV100756767, COSV63294236; called by muse, mutect2
- MAGEB6 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 117/160 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV66872417, COSV66872579; called by muse, mutect2, varscan2
- MALRD1 | c.3506C>T p.S1169L | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs914808919; called by muse, mutect2, varscan2
- MCC | c.829-1G>A p.X277_splice | Splice Site (SNP) | VAF 15/86 reads (17%) | catalogued as COSV100202440; called by muse, varscan2
- MED12L | c.4500G>C p.W1500C | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as COSV99851251; called by muse, mutect2, varscan2
- MED13L | c.4006G>T p.D1336Y | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99927724; called by muse, mutect2, varscan2
- MGAM | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as rs1272804758; called by muse, mutect2, varscan2
- MMP8 | c.62T>A p.F21Y | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV52634271; called by muse, mutect2, varscan2
- MRGPRX1 | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.129); catalogued as COSV57108728; called by muse, mutect2, varscan2
- MROH2B | c.1168C>G p.R390G | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV101270460; called by muse, mutect2, varscan2
- MUC16 | c.21190C>A p.Q7064K | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV67505023; called by muse, mutect2, varscan2
- MUC5B | c.14588C>G p.S4863C | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV71594172; called by muse, mutect2, varscan2
- MVD | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs143846527; called by muse, mutect2, varscan2
- MYF5 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57354993; called by muse, mutect2, varscan2
- MYH4 | c.3854A>G p.H1285R | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs1304664348, COSV55118443; called by muse, mutect2, varscan2
- MYH4 | c.3074C>G p.T1025S | Missense Mutation (SNP) | VAF 52/319 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV55120491; called by muse, mutect2, varscan2
- MYO18B | c.6100G>C p.D2034H | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV59145081; called by muse, mutect2, varscan2
- NAALAD2 | c.1984G>T p.E662* | Nonsense Mutation (SNP) | VAF 21/154 reads (14%) | catalogued as COSV100428137; called by muse, mutect2, varscan2
- NANOS2 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 96/144 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV58025459; called by muse, mutect2, varscan2
- NCOA5 | c.184del p.D62Tfs*23 | Frame Shift Del (DEL) | VAF 233/591 reads (39%) | catalogued as COSV51647395; called by mutect2, pindel, varscan2
- NEMF | c.1880G>C p.G627A | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100027242; called by muse, mutect2, varscan2
- NEURL1 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 62/298 reads (21%) | catalogued as COSV99056681; called by muse, mutect2, varscan2
- NKX2-6 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371546349; called by muse, mutect2, varscan2
- NLRP14 | c.1808C>A p.P603Q | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55069575; called by muse, mutect2, varscan2
- NLRP3 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 103/881 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs200258061, COSV60220327; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP3 | c.3006-1G>T p.X1002_splice | Splice Site (SNP) | VAF 290/451 reads (64%) | catalogued as COSV100276450; called by muse, mutect2, varscan2
- NLRP4 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs574404289, COSV56713214; called by muse, mutect2, varscan2
- NOP2 | c.421G>A p.V141I (on ENST00000322166 / NM_001258308.2; = p.V137I on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1198611770; called by muse, mutect2, varscan2
- NOS2 | c.2599G>T p.E867* | Nonsense Mutation (SNP) | VAF 29/140 reads (21%) | catalogued as COSV58221344; called by muse, mutect2, varscan2
- NOX3 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs765923728; called by muse, mutect2, varscan2
- NRXN3 | c.343G>T p.V115L (on ENST00000557594 / NM_001272020.2; = p.V747L on NM_004796.6) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.136); catalogued as COSV55336026; called by muse, mutect2, varscan2
- NTNG2 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1323792184, COSV62366824; called by muse, mutect2, varscan2
- NTRK1 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV62323355; called by muse, mutect2, varscan2
- NUAK2 | c.502C>A p.Q168K | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65682792; called by muse, mutect2, varscan2
- NUBP2 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51906587; called by muse, mutect2, varscan2
- NUP98 | c.3751G>C p.D1251H (on ENST00000359171 / NM_001365126.1; = p.D1234H on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100263248, COSV61438427; called by muse, mutect2, varscan2
- OCLN | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777819487; called by muse, mutect2, varscan2
- OR10AG1 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV56632331; called by muse, mutect2, varscan2
- OR11H1 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.274); catalogued as rs1365541888; called by mutect2, varscan2
- OR2A25 | c.566C>G p.A189G | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs374373324, COSV68716883, COSV68717463; called by muse, mutect2, varscan2
- OR2B3 | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.327); catalogued as COSV101013854; called by muse, mutect2
- OR2B6 | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV55128844, COSV55129237; called by muse, mutect2, varscan2
- OR2M3 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 76/369 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71758981; called by muse, mutect2, varscan2
- OR2T10 | c.746G>T p.S249I | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV57897051; called by muse, varscan2
- OR2T3 | c.696G>T p.R232S | Missense Mutation (SNP) | VAF 249/401 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as COSV62082389; called by muse, mutect2, varscan2
- OR2T33 | c.854C>A p.P285H | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58813609; called by muse, mutect2
- OR2T33 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV58814873; called by muse, mutect2
- OR2T8 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as rs1330853959; called by muse, mutect2
- OR5B2 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.02); catalogued as rs759864188; called by muse, mutect2, varscan2
- OR5D14 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV59458347; called by muse, mutect2, varscan2
- OR5L2 | c.74T>G p.V25G | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs774230442; called by muse, varscan2
- OR8G1 | c.97G>T p.G33* | Nonsense Mutation (SNP) | VAF 67/301 reads (22%) | catalogued as rs760133703, COSV100422302; called by muse, mutect2, varscan2
- OR8U1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV56414047; called by muse, varscan2
- PARP8 | c.129C>G p.Y43* | Nonsense Mutation (SNP) | VAF 17/148 reads (11%) | catalogued as COSV55866262; called by muse, mutect2, varscan2
- PATE2 | c.78G>A p.A26= | Splice Region (SNP) | VAF 15/115 reads (13%) | catalogued as rs774842820, COSV62069062, COSV62069614; called by muse, mutect2, varscan2
- PCDH19 | c.3422A>G p.K1141R (on ENST00000373034 / NM_001184880.2; = p.K1093R on NM_020766.3) | Missense Mutation (SNP) | VAF 78/111 reads (70%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); catalogued as rs1446535990; called by muse, mutect2, varscan2
- PCDHA10 | c.1139C>A p.A380D | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.02); catalogued as rs202051639; called by muse, mutect2, varscan2
- PCDHA6 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 53/368 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65342498; called by muse, mutect2, varscan2
- PCDHAC1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV53873233; called by muse, mutect2, varscan2
- PCDHB8 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 35/875 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as COSV50753684; called by muse, mutect2
- PCDHB8 | c.1511T>A p.L504Q | Missense Mutation (SNP) | VAF 100/1548 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV50815811; called by muse, mutect2
- PCDHGA11 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.133); catalogued as COSV53914568; called by muse, mutect2, varscan2
- PCDHGA2 | c.1446C>A p.N482K | Missense Mutation (SNP) | VAF 130/242 reads (54%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.015); catalogued as rs745593461, COSV53957199; called by muse, mutect2, varscan2
- PCDHGB1 | c.1271del p.G424Afs*47 | Frame Shift Del (DEL) | VAF 24/146 reads (16%) | catalogued as COSV53894110; called by mutect2, pindel, varscan2
- PCDHGB2 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 49/267 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs1561524605; called by muse, mutect2, varscan2
- PDE11A | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as rs755213594, COSV53700245, COSV99612405; called by muse, mutect2, varscan2
- PDE3B | c.2759G>A p.S920N | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1555007108, COSV56390683; called by muse, mutect2, varscan2
- PDE4B | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370349934; called by muse, mutect2, varscan2
- PDE6H | c.79A>T p.K27* | Nonsense Mutation (SNP) | VAF 93/226 reads (41%) | catalogued as rs762213256; called by muse, mutect2, varscan2
- PDGFRA | c.2683C>A p.P895T | Missense Mutation (SNP) | VAF 128/297 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV104378212; called by muse, mutect2, varscan2
- PDZRN4 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); catalogued as rs908108936, COSV68418256; called by muse, varscan2
- PEG10 | c.7G>A p.E3K (on ENST00000482108 / NM_001040152.2; = p.E37K on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV71788007; called by muse, varscan2
- PGR | c.1844G>T p.R615L | Missense Mutation (SNP) | VAF 76/305 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99678942; called by muse, mutect2, varscan2
- PHF24 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs749347841, COSV54276620; called by muse, mutect2, varscan2
- PHLDB2 | c.3598G>C p.D1200H (on ENST00000393925 / NM_001134439.2; = p.D1157H on NM_145753.2) | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1559930913; called by muse, mutect2, varscan2
- PKD2 | c.1094+1G>T p.X365_splice | Splice Site (SNP) | VAF 31/184 reads (17%) | catalogued as CS065606, CS1110577, COSV52940349; called by muse, varscan2
- PKHD1 | c.5236G>T p.G1746C | Missense Mutation (SNP) | VAF 125/285 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as CM051150, CM051151; called by muse, mutect2, varscan2
- PLSCR1 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.693); catalogued as COSV100678353; called by muse, varscan2
- PMFBP1 | c.1756G>C p.D586H (on ENST00000537465; = p.D581H on NM_031293.3) | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV52824529, COSV99400898; called by muse, mutect2
- POTEJ | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 15/292 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.438); catalogued as rs1306651487; called by muse, mutect2
- POTEJ | c.1835G>C p.S612T | Missense Mutation (SNP) | VAF 48/939 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs778155161; called by muse, mutect2
- PPP2R5D | c.462G>T p.E154D | Missense Mutation (SNP) | VAF 112/446 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as rs762227983; called by muse, mutect2, varscan2
- PPP4R1 | c.1325C>T p.S442L (on ENST00000400556 / NM_001042388.3; = p.S425L on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1228348687; called by muse, mutect2
- PRDM2 | c.4714T>G p.S1572A | Missense Mutation (SNP) | VAF 47/461 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.444); catalogued as rs1019425181; called by muse, mutect2
- PRKD1 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59558168; called by muse, mutect2, varscan2
- PROC | c.969C>A p.S323R | Missense Mutation (SNP) | VAF 230/579 reads (40%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as rs568793026, COSV52165193; called by muse, mutect2, varscan2
- PROKR2 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 48/428 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs146729363, COSV99449940; called by muse, mutect2, varscan2
- PROM2 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.674); catalogued as rs1194469605, COSV58299028; called by muse, mutect2, varscan2
- PSD | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs201151774; called by muse, mutect2, varscan2
- PSMA2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV55031032; called by muse, mutect2, varscan2
- PTGFR | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758033143; called by muse, mutect2, varscan2
- PTPRD | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.031); catalogued as rs771217760, COSV61992327; called by muse, mutect2, varscan2
- PTPRT | c.3287C>A p.A1096D | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100625555; called by muse, mutect2, varscan2
- PYHIN1 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as rs373564494; called by mutect2, varscan2
- QRICH1 | c.1415C>G p.S472C | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV62614643; called by muse, mutect2, varscan2
- RAPGEF4 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 103/180 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV51394142; called by muse, mutect2, varscan2
- RASD1 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 134/176 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs750788635; called by muse, mutect2, varscan2
- RASD2 | c.577C>G p.P193A | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53352583; called by muse, mutect2, varscan2
- RBFOX1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); catalogued as rs1413752645; called by muse, varscan2
- RECK | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as rs1208901676; called by muse, mutect2, varscan2
- REG1A | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52070422; called by muse, mutect2, varscan2
- RFPL3 | c.856T>A p.S286T (on ENST00000249007 / NM_001098535.1; = p.S257T on NM_006604.2) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as COSV50751588; called by muse, mutect2, varscan2
- RIMBP2 | c.1334G>T p.R445M | Missense Mutation (SNP) | VAF 101/308 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs775602620, COSV99898830; called by muse, mutect2, varscan2
- RLF | c.1301T>C p.L434S | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV65650609; called by muse, mutect2, varscan2
- RPL10L | c.484C>A p.R162S | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as COSV53558822, COSV53559285; called by muse, mutect2, varscan2
- RPL10L | c.205C>A p.R69S | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV53560787, COSV53562301; called by muse, mutect2, varscan2
- RPS6KA6 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99425371; called by muse, mutect2, varscan2
- RYR2 | c.4258T>A p.L1420M | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV63693498; called by muse, mutect2, varscan2
- RYR2 | c.14696A>T p.D4899V | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100769507; called by muse, mutect2, varscan2
- SAMSN1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746815653, COSV53467361, COSV53478772; called by muse, mutect2, varscan2
- SCN3A | c.2384G>T p.G795V | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51811827; called by muse, mutect2
- SDR42E1 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 150/272 reads (55%) | catalogued as rs201031405, COSV61093723; called by muse, mutect2, varscan2
- SEMA5A | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 29/302 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs201297356, COSV101228628; called by muse, mutect2
- SI | c.3212C>G p.P1071R | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52275718; called by muse, mutect2, varscan2
- SKOR2 | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.691); catalogued as COSV68550130; called by muse, mutect2, varscan2
- SLC10A2 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55361250; called by muse, mutect2, varscan2
- SLC16A2 | c.1427A>C p.Y476S | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD1010311; called by muse, mutect2, varscan2
- SLC27A4 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 190/257 reads (74%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs1458529052; called by muse, mutect2, varscan2
- SLC30A10 | c.1241G>T p.C414F | Missense Mutation (SNP) | VAF 66/329 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63073235; called by muse, mutect2, varscan2
- SLC8A1 | c.1640C>T p.T547I | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.046); catalogued as rs750207004; called by muse, mutect2, varscan2
- SLITRK5 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100280632; called by muse, mutect2, varscan2
- SLX4IP | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 27/289 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs766026223; called by muse, mutect2
- SND1 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767453550, COSV61234135; called by muse, mutect2, varscan2
- SNTG1 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.982); catalogued as rs1272314072; called by muse, mutect2, varscan2
- SOCS7 | c.1730G>A p.S577N | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as rs1163424652; called by muse, mutect2, varscan2
- SP9 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 148/220 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs1159851267, COSV101209160; called by muse, mutect2, varscan2
- SPATA17 | c.159-1G>A p.X53_splice | Splice Site (SNP) | VAF 26/94 reads (28%) | catalogued as rs1234128977; called by muse, mutect2, varscan2
- SPATA31E1 | c.3572del p.P1191Hfs*49 | Frame Shift Del (DEL) | VAF 40/270 reads (15%) | catalogued as COSV100350152; called by mutect2, pindel, varscan2
- SPEG | c.5569C>G p.Q1857E | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0.018); catalogued as rs373797506; called by muse, mutect2, varscan2
- SPTA1 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 69/371 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as rs1465435093; called by muse, mutect2, varscan2
- SPTB | c.6048G>T p.R2016S | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100731164; called by muse, mutect2, varscan2
- SRRM2 | c.7969C>G p.Q2657E | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as COSV51939872; called by muse, mutect2
- SSC5D | c.4553G>A p.R1518H | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs748017648, COSV67476898; called by muse, mutect2, varscan2
- STAM | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66325342; called by muse, mutect2, varscan2
- STAT4 | c.373G>T p.G125W | Missense Mutation (SNP) | VAF 70/97 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100635933; called by muse, mutect2, varscan2
- SUPT5H | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV63242320; called by muse, mutect2, varscan2
- TBX5 | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs751532982, COSV100092500; called by muse, mutect2, varscan2
- TENM1 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.061); catalogued as rs1246113858; called by muse, mutect2, varscan2
- TENT5D | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 69/86 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV57636130; called by muse, mutect2, varscan2
- TET3 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); catalogued as rs760754169; called by muse, varscan2
- TEX44 | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 57/548 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58355148; called by muse, mutect2, varscan2
- TG | c.1154A>T p.Q385L | Missense Mutation (SNP) | VAF 62/349 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99600162; called by muse, mutect2, varscan2
- THSD7A | c.4790C>A p.P1597Q | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV68472071; called by muse, mutect2, varscan2
- TLR10 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs372475414; called by muse, mutect2, varscan2
- TLR4 | c.487C>T p.Q163* (on ENST00000355622 / NM_138554.5; = p.Q123* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 130/176 reads (74%) | catalogued as COSV62924351; called by muse, mutect2, varscan2
- TMEFF2 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 29/136 reads (21%) | catalogued as rs748224118; called by muse, mutect2, varscan2
- TMEM63C | c.1525G>T p.G509* | Nonsense Mutation (SNP) | VAF 81/150 reads (54%) | catalogued as COSV53602966; called by muse, mutect2, varscan2
- TMEM63C | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 78/148 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53602654; called by muse, mutect2, varscan2
- TOM1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as rs1425030203; called by muse, mutect2, varscan2
- TRA2B | c.783-1G>C p.X261_splice | Splice Site (SNP) | VAF 8/74 reads (11%) | catalogued as COSV52026086; called by muse, mutect2, varscan2
- TRBV2 | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs954694820; called by muse, varscan2
- TRIM49 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 275/740 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV100315930; called by muse, mutect2, varscan2
- TRIM58 | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV63570070; called by muse, varscan2
- TRIM62 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs149870428, COSV99357851; called by muse, mutect2, varscan2
- TRIM7 | c.860G>A p.S287N | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs757682266; called by muse, mutect2, varscan2
- TRPC5 | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 62/74 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53286544; called by muse, mutect2, varscan2
- TRPC6 | c.2197G>T p.E733* | Nonsense Mutation (SNP) | VAF 51/220 reads (23%) | catalogued as COSV60250821; called by muse, mutect2, varscan2
- TRPV5 | c.1227G>T p.R409S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.279); catalogued as rs375589754; called by muse, mutect2, varscan2
- TTN | c.39803T>C p.L13268P (on ENST00000591111; = p.L5844P on NM_003319.4) | Missense Mutation (SNP) | VAF 26/159 reads (16%) | PolyPhen probably damaging (0.999); catalogued as COSV100623612, COSV59967055; called by muse, mutect2, varscan2
- UBE2NL | c.89G>A p.S30N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1216559489; called by muse, mutect2
- UNC80 | c.5174G>T p.R1725L | Missense Mutation (SNP) | VAF 68/97 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99781143; called by muse, mutect2, varscan2
- VEPH1 | c.1690del p.E564Kfs*18 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | catalogued as COSV62881003; called by mutect2, pindel
- VPS13A | c.5160G>C p.E1720D | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1487264324, COSV62426139; called by muse, mutect2, varscan2
- VSTM2A | c.541C>G p.P181A | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as COSV56493262; called by muse, mutect2, varscan2
- VWA2 | c.1280G>T p.R427L | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV100073980; called by muse, mutect2, varscan2
- WDR64 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs1490559690; called by muse, varscan2
- XIRP2 | c.4283C>A p.A1428D (on ENST00000628543; = p.A1603D on NM_152381.6) | Missense Mutation (SNP) | VAF 66/117 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as rs74627077, COSV54728582; called by muse, mutect2, varscan2
- ZIC1 | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.11); catalogued as COSV99292295; called by muse, mutect2, varscan2
- ZNF131 | c.1699G>T p.V567L (on ENST00000509156 / NM_001330707.2; = p.V533L on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 211/380 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV61004224; called by muse, mutect2, varscan2
- ZNF219 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53882394; called by muse, mutect2, varscan2
- ZNF439 | c.227G>C p.R76T | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as COSV58309322; called by muse, mutect2, varscan2
- ZNF516 | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 62/90 reads (69%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs1446166956; called by muse, mutect2, varscan2
- ZNF536 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs200358598; called by muse, mutect2, varscan2
- ZNF646 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV100336674; called by muse, mutect2, varscan2
- ZNF735 | c.896G>A p.C299Y | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70036271; called by muse, mutect2, varscan2
- ZNF804B | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60816523; called by muse, varscan2
- ZNF845 | c.1621C>T p.H541Y | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1417739713, COSV101508839; called by muse, mutect2, varscan2
- ZNF90 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.763); catalogued as COSV101367626; called by muse, mutect2, varscan2
- ABCA13 | c.8000C>G p.S2667C | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA5 | c.2732A>T p.Y911F | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ABCB5 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ABCB5 | c.2243T>A p.V748D (on ENST00000404938 / NM_001163941.2; = p.V303D on NM_178559.6) | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ABL2 | c.259C>T p.Q87* (on ENST00000502732 / NM_007314.4; = p.Q72* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 62/261 reads (24%) | called by muse, mutect2, varscan2
- AC005833.1 | c.1223A>T p.D408V | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ACAN | c.2072C>A p.P691H | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- ACSM5 | c.873C>A p.C291* | Nonsense Mutation (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- ADAD2 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ADAMTS12 | c.1285C>G p.P429A | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS16 | c.31T>A p.L11M | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- ADAMTS16 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 71/253 reads (28%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ADAMTS16 | c.3548C>G p.A1183G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2
- ADAMTS20 | c.2432C>G p.T811S | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAT1 | c.231G>T p.R77S | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.487); called by muse, mutect2
- ADCY6 | c.378C>G p.F126L | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ADGRF4 | c.1568A>G p.Y523C | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL2 | c.4230G>C p.M1410I (on ENST00000370717 / NM_001366005.1; = p.M1354I on NM_012302.4) | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- ADGRL3 | c.923G>T p.G308V (on ENST00000506720 / NM_001322402.2; = p.G240V on NM_015236.6) | Missense Mutation (SNP) | VAF 106/213 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRL3 | c.4223G>T p.R1408M (on ENST00000506720 / NM_001322402.2; = p.R1297M on NM_015236.6) | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- ADGRL4 | c.148G>T p.G50* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- AFF2 | c.3896A>C p.Q1299P | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGBL4 | c.283A>T p.R95W | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- AGPS | c.848C>A p.T283K | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- AGTPBP1 | c.3325G>C p.D1109H (on ENST00000357081 / NM_001330701.2; = p.D1069H on NM_015239.2) | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- AKAP6 | c.4022G>T p.G1341V | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKR1B15 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 225/482 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- AL592490.1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALMS1 | c.3269C>A p.P1090Q | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ALMS1 | c.4830A>G p.I1610M | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- ALS2 | c.2306T>A p.L769* | Nonsense Mutation (SNP) | VAF 27/216 reads (13%) | called by muse, mutect2, varscan2
- ANKFN1 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD24 | c.3206A>G p.K1069R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ANO1 | c.1256G>A p.W419* | Nonsense Mutation (SNP) | VAF 19/138 reads (14%) | called by muse, mutect2
- ANO3 | c.900C>A p.F300L | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANO3 | c.2617G>T p.D873Y | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ANO5 | c.139-1G>T p.X47_splice | Splice Site (SNP) | VAF 164/336 reads (49%) | called by muse, varscan2
- APC | c.8199A>C p.Q2733H | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- APP | c.845C>A p.S282Y | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); called by muse, varscan2
- ARHGEF4 | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 31/321 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); called by muse, mutect2
- ARMC2 | c.2032G>C p.A678P | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ASB10 | c.528C>G p.I176M (on ENST00000420175 / NM_001142459.2; = p.I161M on NM_080871.4) | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ASB14 | c.509T>G p.L170R (on ENST00000389601; = p.L169R on NM_001142733.3) | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASB16 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ASIC4 | c.338C>A p.P113Q | Missense Mutation (SNP) | VAF 168/269 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASTN1 | c.2928C>A p.N976K | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); called by muse, mutect2
- ASZ1 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP1A2 | c.1879G>T p.G627C | Missense Mutation (SNP) | VAF 92/385 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ATP4A | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 72/98 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP9A | c.749A>G p.E250G | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- BACH2 | c.924G>T p.E308D | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BAHCC1 | c.7275G>C p.R2425S | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- BAIAP2L1 | c.247A>T p.K83* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- BCAM | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BICC1 | c.2906G>C p.S969T | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- BICDL2 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- BLMH | c.763A>T p.R255W | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- BMP15 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- BNC1 | c.1448A>C p.K483T | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- BRINP2 | c.547A>T p.S183C | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- BRINP2 | c.1621T>A p.W541R | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BRINP3 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.037); called by muse, mutect2
- BTBD11 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- BTBD9 | c.1141G>T p.A381S | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- C12orf56 | c.208A>T p.I70F | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- C1orf198 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, varscan2
- C3orf20 | c.1265T>C p.L422P | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C7 | c.656G>T p.S219I | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- C7 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAAP1 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 161/326 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAB39L | c.550T>C p.F184L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- CACNG1 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 140/256 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CADM3 | c.848C>T p.A283V (on ENST00000368125 / NM_001127173.3; = p.A317V on NM_021189.5) | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CAPRIN2 | c.2218G>T p.G740C | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CCDC168 | c.191A>T p.K64M | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CCDC39 | c.1581G>T p.Q527H | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- CCDC6 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- CCKBR | c.590C>A p.P197Q | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CCN3 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD1B | c.888A>G p.R296= | Splice Region (SNP) | VAF 17/71 reads (24%) | called by muse, mutect2, varscan2
- CD1E | c.38G>C p.C13S | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CDH10 | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- CDH8 | c.1231G>T p.G411W | Missense Mutation (SNP) | VAF 38/407 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDRT15L2 | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- CELSR3 | c.208_209dup p.R71Sfs*107 | Frame Shift Ins (INS) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- CEP295NL | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CER1 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CFAP47 | c.5335G>T p.E1779* | Nonsense Mutation (SNP) | VAF 16/25 reads (64%) | called by muse, varscan2
- CHCHD10 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CHODL | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CHST13 | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLEC14A | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 78/129 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CLSTN2 | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- CNNM1 | c.1639G>T p.V547L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CNOT4 | c.255A>T p.K85N | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- CNTN2 | c.47C>G p.A16G | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNTN3 | c.2672G>T p.S891I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNTN3 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP2 | c.612G>T p.K204N | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- CNTNAP2 | c.3884C>T p.T1295I | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CNTNAP3 | c.3300del p.D1100Efs*7 | Frame Shift Del (DEL) | VAF 68/315 reads (22%) | called by pindel, varscan2
- COL11A2 | c.2414G>A p.G805E (on ENST00000341947 / NM_080680.3; = p.G698E on NM_080679.2) | Missense Mutation (SNP) | VAF 81/367 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL12A1 | c.2668G>T p.G890W | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL22A1 | c.1450G>C p.G484R | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- COL24A1 | c.1537G>T p.G513C | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL24A1 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL3A1 | c.2698G>A p.G900S | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A2 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COL6A5 | c.2781del p.E927Dfs*15 | Frame Shift Del (DEL) | VAF 70/270 reads (26%) | called by mutect2, pindel, varscan2
- CPE | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CPXCR1 | c.415A>T p.R139* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- CR2 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRAT | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CRISPLD1 | c.624A>T p.P208= | Splice Region (SNP) | VAF 81/119 reads (68%) | called by muse, mutect2, varscan2
- CRMP1 | c.186del p.R63Gfs*21 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | called by mutect2, pindel, varscan2
- CRYBA4 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSE1L | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CSGALNACT1 | c.1542C>A p.H514Q | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, varscan2
- CSMD1 | c.9130C>G p.L3044V (on ENST00000520002; = p.L3043V on NM_033225.6) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.906); called by muse, mutect2
- CSMD1 | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD3 | c.4910C>G p.P1637R (on ENST00000297405 / NM_001363185.1; = p.P1533R on NM_052900.3) | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, varscan2
- CSMD3 | c.703T>G p.C235G | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CTNNA3 | c.1127A>C p.Q376P | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CTNND1 | c.2670G>T p.M890I | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CTNND2 | c.1789C>A p.L597M | Missense Mutation (SNP) | VAF 41/345 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTTNBP2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CUBN | c.3361G>T p.G1121* | Nonsense Mutation (SNP) | VAF 114/225 reads (51%) | called by muse, mutect2, varscan2
- CUL3 | c.997G>T p.G333* | Nonsense Mutation (SNP) | VAF 59/95 reads (62%) | called by muse, mutect2, varscan2
- CYP24A1 | c.1501C>A p.L501M | Missense Mutation (SNP) | VAF 94/385 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- CYP26C1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CYP2C9 | c.1291+2T>A p.X431_splice | Splice Site (SNP) | VAF 36/208 reads (17%) | called by muse, mutect2, varscan2
- CYP4X1 | c.92del p.K31Sfs*73 | Frame Shift Del (DEL) | VAF 22/146 reads (15%) | called by mutect2, pindel, varscan2
- CYP7B1 | c.436dup p.Q146Pfs*21 | Frame Shift Ins (INS) | VAF 37/194 reads (19%) | called by mutect2, varscan2
- CYP7B1 | c.434dup p.L145Ffs*22 | Frame Shift Ins (INS) | VAF 29/221 reads (13%) | called by mutect2*, pindel, varscan2*
- DCAF4L2 | c.806A>T p.H269L | Missense Mutation (SNP) | VAF 56/295 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, varscan2
- DDX1 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DDX54 | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DGKG | c.1331G>C p.G444A | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DIAPH3 | c.3079C>A p.R1027S (on ENST00000400324 / NM_001042517.2; = p.R764S on NM_030932.3) | Missense Mutation (SNP) | VAF 104/153 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DISP1 | c.15T>A p.N5K | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DMD | c.926C>G p.T309S | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DMWD | c.71C>G p.S24W | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); called by muse, mutect2
- DMXL1 | c.3713A>G p.Y1238C | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH10 | c.7898G>A p.G2633E (on ENST00000409039; = p.G2572E on NM_207437.3) | Missense Mutation (SNP) | VAF 122/1068 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- DNAH5 | c.3299C>T p.P1100L | Missense Mutation (SNP) | VAF 31/317 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- DNAH5 | c.2783C>G p.S928C | Missense Mutation (SNP) | VAF 49/424 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH7 | c.7670A>T p.Y2557F | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.3760G>C p.V1254L | Missense Mutation (SNP) | VAF 22/259 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- DNAH9 | c.11875C>A p.Q3959K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- DNAH9 | c.11876A>G p.Q3959R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- DNAJB4 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNM3 | c.1911+1G>T p.X637_splice (on ENST00000355305 / NM_001350206.2; = p.X627_splice on NM_015569.5) | Splice Site (SNP) | VAF 32/128 reads (25%) | called by muse, mutect2, varscan2
- DOC2B | c.923+1G>C p.X308_splice | Splice Site (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- DOCK1 | c.2785G>C p.G929R | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- DOCK10 | c.3727A>T p.N1243Y | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- DPRX | c.228C>A p.C76* | Nonsense Mutation (SNP) | VAF 53/80 reads (66%) | called by muse, mutect2, varscan2
- DPY19L2 | c.2188_2189delinsT p.P730Sfs*26 | Frame Shift Del (DEL) | VAF 35/220 reads (16%) | called by pindel, varscan2*
- DSE | c.1346G>T p.G449V | Missense Mutation (SNP) | VAF 70/118 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSEL | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTNA | c.2098G>T p.D700Y | Missense Mutation (SNP) | VAF 114/191 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- DTX2 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- DUSP7 | c.145dup p.A49Gfs*136 | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | called by mutect2, pindel
- EDARADD | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELAPOR1 | c.201G>C p.R67S | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EMC2 | c.363+8G>T | Splice Region (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- EMILIN3 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 133/250 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EML2 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 56/86 reads (65%) | called by muse, mutect2, varscan2
- EPG5 | c.1009-1G>T p.X337_splice | Splice Site (SNP) | VAF 14/55 reads (25%) | called by muse, varscan2
- EPHA7 | c.2101G>T p.V701F | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EPHB6 | c.1363G>T p.V455L | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2
- EPHB6 | c.2657G>T p.G886V | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERAL1 | c.284-1G>C p.X95_splice | Splice Site (SNP) | VAF 22/116 reads (19%) | called by muse, varscan2
- ERBB4 | c.2360G>T p.C787F | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ERICH3 | c.3056C>T p.A1019V | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated, low confidence (0.32); called by muse, mutect2, varscan2
- ERN1 | c.2626del p.E876Rfs*29 | Frame Shift Del (DEL) | VAF 70/290 reads (24%) | called by mutect2, pindel, varscan2
- ERO1A | c.716-5C>G | Splice Region (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- EXOC3L4 | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- EXTL2 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EZH1 | c.1807A>T p.K603* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- FAM104B | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- FAM47A | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM47A | c.198A>T p.E66D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- FAM47C | c.2454G>T p.K818N | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.412); called by muse, varscan2
- FAM47C | c.2539C>A p.H847N | Missense Mutation (SNP) | VAF 96/146 reads (66%) | SIFT tolerated (0.16); PolyPhen benign (0.131); called by muse, varscan2
- FAN1 | c.1817C>A p.A606E | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT tolerated (0.48); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FANCF | c.902A>C p.D301A | Missense Mutation (SNP) | VAF 146/421 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- FASN | c.4874_4875del p.S1625Cfs*78 | Frame Shift Del (DEL) | VAF 78/728 reads (11%) | called by pindel, varscan2
- FBN3 | c.3689C>A p.T1230K | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- FBXL18 | c.530A>T p.K177M | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FBXO3 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- FCGR1A | c.911T>C p.L304S | Missense Mutation (SNP) | VAF 49/480 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- FFAR4 | c.1023del p.C342Afs*21 | Frame Shift Del (DEL) | VAF 44/313 reads (14%) | called by mutect2, pindel, varscan2
- FGF2 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- FGL2 | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FH | c.1369A>G p.T457A | Missense Mutation (SNP) | VAF 101/509 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- FLG | c.6995C>G p.S2332C | Missense Mutation (SNP) | VAF 485/857 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FLG | c.4910A>C p.Q1637P | Missense Mutation (SNP) | VAF 48/431 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FLG2 | c.4442A>G p.Y1481C | Missense Mutation (SNP) | VAF 72/729 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLT1 | c.449A>C p.E150A | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.676); called by muse, varscan2
- FMN2 | c.1986+2T>A p.X662_splice | Splice Site (SNP) | VAF 23/150 reads (15%) | called by muse, mutect2, varscan2
- FOLH1 | c.1263G>T p.W421C | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXP1 | c.1867G>C p.G623R | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- FRAS1 | c.7444G>A p.E2482K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- FRG2B | c.660G>T p.Q220H | Missense Mutation (SNP) | VAF 98/278 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, varscan2
- FRYL | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.186); called by muse, mutect2
- FSCB | c.884C>A p.P295Q | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- FSIP1 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 34/60 reads (57%) | called by muse, varscan2
- FSIP2 | c.16249C>A p.Q5417K | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- GBA3 | c.138C>A p.N46K | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GBP5 | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GCH1 | c.649G>T p.G217C | Missense Mutation (SNP) | VAF 156/301 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDE1 | c.639G>C p.M213I | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- GFI1 | c.488A>T p.H163L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GJB5 | c.384G>T p.W128C | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GJC1 | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GMPS | c.2079G>T p.E693D | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGB1 | c.9181G>T p.E3061* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | called by muse, mutect2, varscan2
- GOLGB1 | c.3137A>T p.Y1046F | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- GOLPH3 | c.383C>A p.T128K | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GPATCH3 | c.865C>G p.H289D | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPATCH8 | c.920A>T p.K307M | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GPR25 | c.317C>A p.P106Q | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- GPRASP1 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- GPRC6A | c.1955G>T p.G652V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- GPRC6A | c.1954G>T p.G652* | Nonsense Mutation (SNP) | VAF 22/90 reads (24%) | called by muse, varscan2
- GREB1L | c.3635C>G p.P1212R | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIA1 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- GRID1 | c.2309A>G p.Y770C | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIK5 | c.1341C>A p.C447* | Nonsense Mutation (SNP) | VAF 89/144 reads (62%) | called by muse, mutect2, varscan2
- GRIN3A | c.716A>T p.Q239L | Missense Mutation (SNP) | VAF 136/199 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- GRM4 | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- GRM5 | c.2788T>A p.W930R (on ENST00000305447 / NM_001143831.2; = p.W898R on NM_000842.4) | Missense Mutation (SNP) | VAF 75/131 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRM5 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GRPR | c.586T>A p.C196S | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRXCR2 | c.157T>A p.F53I | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GSTA1 | c.454A>C p.K152Q | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.01); called by muse, mutect2
- GTPBP8 | c.810C>G p.H270Q | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- GXYLT1 | c.319A>T p.S107C | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.267); called by mutect2, varscan2
- GYS2 | c.51G>T p.Q17H | Missense Mutation (SNP) | VAF 82/280 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- HCAR2 | c.655C>G p.Q219E | Missense Mutation (SNP) | VAF 42/337 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by mutect2, varscan2
- HCAR3 | c.655C>G p.Q219E | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- HDAC11 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.209); called by muse, varscan2
- HECTD4 | c.2821G>T p.V941F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEPACAM2 | c.1243G>T p.V415F (on ENST00000394468 / NM_001039372.4; = p.V403F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HERC2 | c.13462G>A p.E4488K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HES1 | c.383G>T p.C128F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- HHAT | c.1178G>T p.W393L | Missense Mutation (SNP) | VAF 38/359 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIVEP1 | c.6738G>T p.M2246I | Missense Mutation (SNP) | VAF 140/235 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- HOXB7 | c.504C>G p.I168M | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- HOXD9 | c.438C>A p.S146R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSD11B1 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 105/509 reads (21%) | called by muse, mutect2, varscan2
- HSPG2 | c.4049C>T p.P1350L | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- HTR5A | c.465G>C p.K155N | Missense Mutation (SNP) | VAF 60/432 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- HTR5A | c.694G>T p.G232C | Missense Mutation (SNP) | VAF 17/240 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2
- HYAL4 | c.866_867insA p.T290Hfs*6 | Frame Shift Ins (INS) | VAF 24/192 reads (13%) | called by mutect2, pindel*, varscan2
- IFI16 | c.1853T>G p.I618S (on ENST00000295809 / NM_001364867.2; = p.I562S on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/481 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- IGFN1 | c.3116-2A>T p.X1039_splice (on ENST00000295591 / NM_001367841.1; = p.X3496_splice on NM_001164586.2) | Splice Site (SNP) | VAF 90/147 reads (61%) | called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 111/527 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); called by muse, varscan2
- IGKV3-15 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 97/185 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IGKV6-21 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 50/349 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- IGLC7 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 68/393 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- IL1RAPL1 | c.92G>A p.C31Y | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- INPP4A | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- IRAK1BP1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 73/120 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- IRF8 | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 253/477 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGAM | c.3362T>A p.L1121Q (on ENST00000648685 / NM_001145808.2; = p.L1120Q on NM_000632.4) | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR1 | c.6572A>C p.K2191T (on ENST00000354582; = p.K2136T on NM_002222.7) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPR2 | c.5333G>T p.G1778V | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- ITPRID2 | c.3256G>T p.G1086C | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAG1 | c.2576C>A p.S859* | Nonsense Mutation (SNP) | VAF 66/463 reads (14%) | called by muse, mutect2, varscan2
- JAG1 | c.2256del p.C753Afs*67 | Frame Shift Del (DEL) | VAF 71/501 reads (14%) | called by mutect2, pindel, varscan2
- KALRN | c.4925A>G p.D1642G | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KATNIP | c.74A>T p.K25M | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KCNA5 | c.190G>T p.V64L | Missense Mutation (SNP) | VAF 76/139 reads (55%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ15 | c.622A>T p.I208F | Missense Mutation (SNP) | VAF 76/143 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KCNK16 | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 141/279 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- KCTD8 | c.709G>C p.V237L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- KDM6A | c.3290A>C p.K1097T | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- KDR | c.2140G>T p.V714L | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- KERA | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KHSRP | c.547+1G>T p.X183_splice | Splice Site (SNP) | VAF 23/101 reads (23%) | called by muse, mutect2, varscan2
- KIF1A | c.3643C>A p.P1215T | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT tolerated (0.72); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF1A | c.3377C>A p.P1126Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- KIF1A | c.3124G>T p.G1042C | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIFAP3 | c.1926G>A p.M642I | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KL | c.1337A>C p.K446T | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); called by muse, varscan2
- KMT2A | c.7604C>G p.S2535C | Missense Mutation (SNP) | VAF 30/339 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- KNDC1 | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 133/233 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- KPRP | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 42/449 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- KREMEN2 | c.717C>A p.Y239* | Nonsense Mutation (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2
- KREMEN2 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); called by muse, mutect2
- KRTAP19-6 | c.80G>T p.C27F | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KRTAP20-3 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- LACTBL1 | c.610T>G p.S204A (on ENST00000618559; = p.S249A on NM_001289974.2) | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, varscan2
- LACTBL1 | c.551C>T p.S184L (on ENST00000618559; = p.S229L on NM_001289974.2) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- LAMA2 | c.4838A>C p.E1613A | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LAMB4 | c.3374G>T p.C1125F | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMB4 | c.2375C>G p.P792R | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- LARGE1 | c.1191del p.R398Afs*5 | Frame Shift Del (DEL) | VAF 61/167 reads (37%) | called by mutect2, pindel, varscan2
- LGR6 | c.842C>G p.P281R (on ENST00000367278 / NM_001017403.1; = p.P229R on NM_021636.3) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LHX1 | c.954del p.P319Rfs*82 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | called by mutect2, pindel, varscan2
- LIG4 | c.1718G>T p.G573V | Missense Mutation (SNP) | VAF 230/336 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- LINGO4 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- LNX2 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 47/78 reads (60%) | called by muse, mutect2, varscan2
- LONP2 | c.317G>T p.C106F | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- LPAR5 | c.670A>T p.T224S | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- LRFN5 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- LRIT1 | c.122+2T>A p.X41_splice | Splice Site (SNP) | VAF 34/201 reads (17%) | called by muse, mutect2, varscan2
- LRP1B | c.12416G>C p.R4139P | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- LRP1B | c.2144A>G p.Y715C | Missense Mutation (SNP) | VAF 61/496 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, varscan2
- LRP4 | c.4725G>T p.Q1575H | Missense Mutation (SNP) | VAF 236/444 reads (53%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by mutect2, varscan2
- LRRC47 | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 95/176 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MACF1 | c.10594G>A p.E3532K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | called by muse, varscan2
- MAGEA1 | c.65C>A p.A22D | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- MAGEB17 | c.484T>C p.F162L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCHF7 | c.1514A>T p.D505V | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MARK1 | c.967T>C p.Y323H | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MATR3 | c.1614G>C p.E538D | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MEIS1 | c.726C>A p.D242E | Missense Mutation (SNP) | VAF 73/310 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MFSD14B | c.758C>G p.T253S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- MFSD4A | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- MIA3 | c.2221_2229del p.R741_K743del | In Frame Del (DEL) | VAF 64/145 reads (44%) | called by mutect2, pindel, varscan2
- MMAB | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 168/394 reads (43%) | called by muse, mutect2, varscan2
- MMP27 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MMRN1 | c.261A>C p.E87D | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MORN2 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MPEG1 | c.1852G>T p.A618S | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPPED2 | c.261C>A p.F87L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRE11 | c.1712G>A p.G571D | Missense Mutation (SNP) | VAF 44/330 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); called by muse, varscan2
- MROH2B | c.2221G>C p.G741R | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH2B | c.2116G>T p.G706* | Nonsense Mutation (SNP) | VAF 25/196 reads (13%) | called by muse, mutect2, varscan2
- MSX2 | c.754G>C p.V252L | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MTA2 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MTCH1 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- MTERF1 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- MTRNR2L5 | c.71T>A p.V24E | Missense Mutation (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- MUC16 | c.16058C>A p.T5353K | Missense Mutation (SNP) | VAF 81/121 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MUC16 | c.15717T>A p.D5239E | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.8533A>T p.T2845S | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- MXRA5 | c.2363C>A p.A788D | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYH1 | c.1114C>A p.R372S | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH13 | c.4492C>A p.Q1498K | Missense Mutation (SNP) | VAF 104/143 reads (73%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- MYH2 | c.2430G>A p.M810I | Missense Mutation (SNP) | VAF 49/304 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYH4 | c.2546C>T p.T849I | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NAV3 | c.2380G>T p.G794* | Nonsense Mutation (SNP) | VAF 44/137 reads (32%) | called by muse, mutect2, varscan2
- NAV3 | c.2381G>T p.G794V | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NAV3 | c.3245G>T p.S1082I | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NBPF20 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 78/938 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2
- NCAM1 | c.1519del p.A507Qfs*70 (on ENST00000316851 / NM_181351.5; = p.A497Qfs*70 on NM_000615.7) | Frame Shift Del (DEL) | VAF 28/186 reads (15%) | called by mutect2, pindel, varscan2
- NDEL1 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NEB | c.17308C>T p.H5770Y | Missense Mutation (SNP) | VAF 24/417 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.98); called by muse, mutect2
- NEB | c.12127G>A p.E4043K | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); called by muse, mutect2
- NETO2 | c.704A>T p.K235M | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NEUROD1 | c.1045C>A p.Q349K | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- NID1 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 175/296 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- NLRP3 | c.1143C>G p.F381L | Missense Mutation (SNP) | VAF 233/375 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLRP4 | c.1966G>A p.V656M | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT tolerated (0.15); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- NLRP8 | c.1944C>A p.C648* | Nonsense Mutation (SNP) | VAF 44/74 reads (59%) | called by muse, mutect2, varscan2
- NMS | c.114G>T p.L38F | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- NOS3 | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2
- NPAP1 | c.2300G>T p.G767V | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- NPLOC4 | c.653A>T p.Q218L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPTX1 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- NRAP | c.139A>T p.S47C | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRXN1 | c.3350del p.P1117Hfs*38 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | called by mutect2, pindel, varscan2
- NRXN1 | c.1969C>G p.R657G | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- NUBP2 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- NUF2 | c.482A>G p.E161G | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2
- NUF2 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2
- NUP205 | c.1858del p.E620Nfs*10 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel, varscan2
- OBP2A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 54/279 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OBSCN | c.16635G>T p.E5545D | Missense Mutation (SNP) | VAF 25/275 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- OCIAD1 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- OCSTAMP | c.143T>A p.L48Q | Missense Mutation (SNP) | VAF 42/422 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- ONECUT3 | c.1451C>A p.P484H | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- OR10K1 | c.80T>A p.L27H | Missense Mutation (SNP) | VAF 45/335 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR11L1 | c.606del p.S203Qfs*11 | Frame Shift Del (DEL) | VAF 242/560 reads (43%) | called by pindel, varscan2
- OR11L1 | c.548C>A p.P183Q | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- OR1C1 | c.119T>A p.L40* | Nonsense Mutation (SNP) | VAF 85/493 reads (17%) | called by muse, mutect2, varscan2
- OR1D2 | c.725C>A p.A242D | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- OR2B6 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR2B6 | c.872C>A p.T291K | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- OR2F1 | c.753C>G p.C251W | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4D5 | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 142/264 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR4F4 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- OR4K2 | c.436G>C p.V146L | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR51F1 | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR51S1 | c.590G>T p.C197F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR52D1 | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- OR5AP2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- OR5H1 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 104/257 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR5H6 | c.439C>T p.L147F (on ENST00000642105; = p.L131F on NM_001005479.2) | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- OR5M1 | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR6M1 | c.764T>C p.V255A | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- OSBPL10 | c.2293T>A p.*765Rext*15 | Nonstop Mutation (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- OSBPL3 | c.1736T>C p.L579P | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- OTOG | c.6526T>G p.L2176V | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- P3H3 | c.861G>A p.W287* | Nonsense Mutation (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2, varscan2
- PADI6 | c.860C>G p.S287* | Nonsense Mutation (SNP) | VAF 26/145 reads (18%) | called by muse, mutect2, varscan2
- PAGR1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 49/366 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PAGR1 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PATZ1 | c.709A>C p.M237L | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PCDH17 | c.3427G>C p.D1143H | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCDH7 | c.1480G>C p.D494H | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB13 | c.2197C>A p.P733T | Missense Mutation (SNP) | VAF 109/221 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- PCDHB7 | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 89/145 reads (61%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDHGA7 | c.1177A>T p.K393* | Nonsense Mutation (SNP) | VAF 49/100 reads (49%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCK1 | c.268A>C p.S90R | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- PDE11A | c.2340C>A p.Y780* | Nonsense Mutation (SNP) | VAF 60/442 reads (14%) | called by muse, mutect2, varscan2
- PDE1A | c.1246T>C p.S416P | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PDE3B | c.3284C>A p.S1095Y | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.269); called by muse, mutect2, varscan2
722 further variants in this file (230 protein-altering or splice-affecting, 307 silent, 185 other) are not listed here.
